Gene-level copy-number profile of specimen HCM-CSHL-0636-C02-85A from HCMI case HCM-CSHL-0636-C02, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0636-C02-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 090a5e7e-b669-4f51-b580-6702409b5faf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0636-C02-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/aed3500c-5f8a-4143-840f-17d19ccfb0b4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 761; copy number 2: 14,694; copy number 3: 21,488; copy number 4: 15,575; copy number 5: 3,945; copy number 6: 2,046; copy number 7: 52; copy number 8: 146; copy number 9: 74; copy number 10: 39; copy number 11: 2; copy number 23: 79; copy number 28: 1; copy number 31: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,507,764–49,524,185, 3 genes: AC119751.5, AC119751.2, AC119751.8.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 395 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:91,638,847–95,296,415, 66 genes, copy number 8–9 (broad region; genes not listed).
- chr7:106,125,371–106,126,700, 1 gene, copy number 7: DCAF13P1.
- chr7:107,563,484–108,569,666, 21 genes, copy number 7 (within-gene range 6–7): DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32.
- chr7:108,909,453–109,326,315, 3 genes, copy number 7: AC004014.1, BUB3P1, AC002386.1.
- chr9:3,526,723–6,197,248, 61 genes, copy number 7–11 (broad region; genes not listed).
- chr11:69,072,915–69,162,440, 1 gene, copy number 8 (within-gene range 4–8): AP003071.5.
- chr11:69,103,493–72,843,674, 131 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr12:66,023,620–70,637,440, 100 genes, copy number 10–31 (broad region; genes not listed).
- chr16:51,755,325–51,788,208, 1 gene, copy number 7: LINC01571.
- chr17:38,351,844–38,405,593, 1 gene, copy number 7: SOCS7.
- chr17:38,530,031–38,605,952, 1 gene, copy number 7 (within-gene range 5–7): SRCIN1.
- chr19:55,132,698–55,209,506, 8 genes, copy number 7: TNNT1, TNNI3, AC010327.2, DNAAF3, AC010327.4, AC010327.1, SYT5, PTPRH.

Autosomal genes at a single copy (total copy number 1): 761. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
